Somatic mutation profile of tumor specimen TCGA-L6-A4EQ-01A (aliquot TCGA-L6-A4EQ-01A-11D-A257-08) from TCGA case TCGA-L6-A4EQ, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 47.5 years (17,351 days).
Specimen TCGA-L6-A4EQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 15f17ffa-950a-48a5-999f-f4a648a3ec53.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-L6-A4EQ-10A (Blood Derived Normal), aliquot TCGA-L6-A4EQ-10A-01D-A25A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/963e2fbf-89dd-4341-85e9-fc075d946058

The open-access MAF lists 18 somatic variants for this specimen: 12 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 4, 5'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ANKRD35 | c.1760G>C p.R587T | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT tolerated (0.54); PolyPhen benign (0.015); catalogued as COSV100841598; called by muse, mutect2, varscan2
- ATP2B4 | c.933C>G p.N311K | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.012); catalogued as COSV100396898, COSV100398186; called by muse, mutect2, varscan2
- FBN3 | c.4889G>A p.C1630Y | Missense Mutation (SNP) | VAF 41/88 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99559190; called by muse, mutect2, varscan2
- KCNH1 | c.1689G>A p.M563I (on ENST00000271751 / NM_172362.3; = p.M536I on NM_002238.4) | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as COSV99656584; called by muse, mutect2, varscan2
- LRRC19 | c.80G>C p.R27T | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV101195758; called by muse, mutect2
- MEFV | c.1811C>T p.A604V | Missense Mutation (SNP) | VAF 11/346 reads (3%) | SIFT tolerated (0.25); PolyPhen benign (0.017); catalogued as rs1458834927, COSV99560047; called by muse, mutect2
- MSH5 | c.1766T>A p.V589D | Missense Mutation (SNP) | VAF 55/137 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV100994617; called by muse, mutect2, varscan2
- PLCD1 | c.1130C>G p.A377G | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99378224; called by muse, mutect2, varscan2
- TRIM26 | c.1459C>T p.R487W | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs759450962, COSV101443909; called by muse, mutect2, varscan2
- USP9X | c.3247C>G p.P1083A | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV100198260; called by muse, varscan2
- MROH5 | c.3784A>T p.T1262S | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.233); called by muse, mutect2
- ADAMTSL1 | c.3825G>A p.T1275= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs759435938, COSV101001020; called by muse, varscan2
- ALLC | c.963T>A p.L321= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV99377289; called by muse, mutect2, varscan2
- PLA2G15 | c.612G>A p.T204= | Silent (SNP) | VAF 31/69 reads (45%) | catalogued as rs747423436, COSV54724701; called by muse, mutect2, varscan2
- RBP1 | c.45G>A p.E15= (on ENST00000619087 / NM_001365940.2; = p.E77= on NM_002899.5) | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as rs753311032, COSV99218585, COSV99218965; called by muse, mutect2, varscan2
- C11orf58 | c.-1G>C | 5'UTR (SNP) | VAF 6/72 reads (8%) | catalogued as rs1489450947, COSV99930132; called by muse, mutect2
- UBTFL2 | n.595C>G | RNA (SNP) | VAF 9/52 reads (17%) | called by mutect2, varscan2
